Gene-level copy-number profile of tumor specimen TCGA-22-1012-01A from TCGA case TCGA-22-1012, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 80.1 years (29,273 days).
Specimen TCGA-22-1012-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.06f2dea9-0647-4291-b807-2fda9d45151b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-1012-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d1533e41-7600-47dd-9847-842ef4566a10

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 20,023; copy number 2: 16,235; copy number 3: 20,406; copy number 4: 2,284; copy number 5: 72; copy number 6: 738.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-1012-01A-01D-0685-01): tumor purity 0.32, ploidy 3.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:231,921,809–232,611,971, 23 genes (within-gene range 0–2): NPPC, DIS3L2, AC019130.1, MIR562, NRBF2P6, ECEL1P3, AC068134.3, ALPP, AC068134.1, ECEL1P2, ALPG, ECEL1P1, AC068134.2, DIS3L2P1, ALPI, ECEL1, PRSS56, CHRND, CHRNG, TIGD1, MIR5001, EIF4E2, AC073254.1.
- chr2:233,205,199–233,833,423, 30 genes (within-gene range 0–1): RN7SL32P, ATG16L1, SCARNA5, SCARNA6, SAG, AC013726.1, DGKD, Y_RNA, USP40, PPFIA1P1, UGT1A12P, UGT1A11P, UGT1A8, UGT1A10, UGT1A13P, UGT1A9, UGT1A7, UGT1A6, AC114812.2, UGT1A5, UGT1A4, RPL17P11, UGT1A3, AC114812.3, DNAJB3, UGT1A2P, AC114812.4, AC114812.1, UGT1A1, MROH2A.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 19,109. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
